Somatic mutation profile of tumor specimen 0DY8KN from CCDI case PBCSJL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mixed type rhabdomyosarcoma; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 13.2 years (4,833 days).
Specimen 0DY8KN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8843ff99-b262-4cad-9b34-c630a1681c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY8KI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58eba156-54d0-4e66-8ef1-b4aa00ccb346

The open-access MAF lists 33 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, 3'UTR 5, In Frame Ins 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 407/1402 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- APC | c.4478C>T p.T1493M | Missense Mutation (SNP) | VAF 424/1218 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374892194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP22 | c.1535G>T p.W512L | Missense Mutation (SNP) | VAF 117/439 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as COSV50933067; called by muse, mutect2, varscan2
- GRIA3 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 517/807 reads (64%) | SIFT tolerated (0.86); PolyPhen benign (0.031); catalogued as COSV52081451; called by muse, mutect2, varscan2
- MYO15B | c.4024G>A p.G1342R | Missense Mutation (SNP) | VAF 110/301 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as rs1364420475; called by muse, mutect2, varscan2
- OBSCN | c.14449G>A p.V4817I | Missense Mutation (SNP) | VAF 218/574 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs753777186, COSV52755385; called by muse, mutect2, varscan2
- RANBP2 | c.3772G>C p.A1258P | Missense Mutation (SNP) | VAF 338/1448 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51702010; called by muse, mutect2, varscan2
- SIDT1 | c.1457C>A p.A486D | Missense Mutation (SNP) | VAF 166/692 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53504412; called by muse, mutect2, varscan2
- CEP68 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 148/759 reads (19%) | called by muse, mutect2, varscan2
- COQ5 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 159/621 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSPG4 | c.3935C>A p.A1312E | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.164); called by muse, mutect2
- KCNJ12 | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- MAGEA12 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2
- NEXN | c.1054-3T>C | Splice Region (SNP) | VAF 278/777 reads (36%) | called by muse, mutect2, varscan2
- WDR93 | c.407A>C p.Y136S | Missense Mutation (SNP) | VAF 286/836 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- YBX1 | c.846_863dup p.N284_R289dup | In Frame Ins (INS) | VAF 162/874 reads (19%) | called by mutect2, varscan2
- ZDBF2 | c.6633_6636del p.S2212Ffs*37 | Frame Shift Del (DEL) | VAF 514/2017 reads (25%) | called by mutect2, varscan2
- ZNF680 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 753/1555 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3 | c.4677C>T p.D1559= | Silent (SNP) | VAF 38/576 reads (7%) | catalogued as rs1490765170; called by muse, mutect2
- GLB1L2 | c.1641A>G p.L547= | Silent (SNP) | VAF 198/705 reads (28%) | called by muse, mutect2, varscan2
- PCDHB1 | c.1731G>T p.V577= | Silent (SNP) | VAF 265/690 reads (38%) | called by muse, mutect2, varscan2
- PDE3A | c.621G>A p.R207= | Silent (SNP) | VAF 264/1126 reads (23%) | called by muse, mutect2, varscan2
- PRR32 | c.174C>T p.S58= | Silent (SNP) | VAF 457/694 reads (66%) | catalogued as rs775137715, COSV64420319, COSV64420808; called by muse, mutect2, varscan2
- QRFPR | c.507C>G p.V169= | Silent (SNP) | VAF 271/767 reads (35%) | called by muse, mutect2, varscan2
- RTL9 | c.2718C>A p.A906= | Silent (SNP) | VAF 270/370 reads (73%) | called by muse, mutect2, varscan2
- ZNF616 | c.1284G>A p.Q428= | Silent (SNP) | VAF 367/1312 reads (28%) | called by muse, mutect2, varscan2
- CATIP | c.320-97A>G | Intron (SNP) | VAF 23/98 reads (23%) | catalogued as rs1474454466; called by muse, mutect2, varscan2
- MYO1C | c.-11C>T | 5'UTR (SNP) | VAF 62/223 reads (28%) | catalogued as rs1257487628, COSV100233982; called by muse, mutect2, varscan2
- PPP1R3C | c.*32T>C | 3'UTR (SNP) | VAF 87/397 reads (22%) | called by muse, mutect2, varscan2
- PRPSAP2 | c.*87C>G | 3'UTR (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- SIT1 | c.*49G>T | 3'UTR (SNP) | VAF 72/211 reads (34%) | called by muse, mutect2, varscan2
- TNS3 | c.*80T>G | 3'UTR (SNP) | VAF 71/259 reads (27%) | called by muse, mutect2, varscan2
- TSPAN3 | c.*19G>A | 3'UTR (SNP) | VAF 111/285 reads (39%) | called by muse, mutect2, varscan2
